Gene-level copy-number profile of tumor specimen TCGA-DD-A11D-01A from TCGA case TCGA-DD-A11D, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.5 years (21,003 days).
Specimen TCGA-DD-A11D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.9dd0ed9f-8da8-4ae2-b5ad-7d57e580f1d4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A11D-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/287cf8ce-f705-44e6-967f-0f9bccbef91c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,411; copy number 2: 48,600; copy number 3: 9,791; copy number 5: 1; copy number 6: 6; copy number 7: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A11D-01A-11D-A12Y-01): tumor purity 0.79, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:6,901,022–6,918,715, 1 gene, copy number 7: AL158817.1.
- chr6:10,434,316–10,478,502, 4 genes, copy number 7 (within-gene range 2–7): MIR5689HG, MIR5689, MRPL48P1, LINC02522.
- chr6:33,131,216–33,143,325, 1 gene, copy number 7: HLA-DPA3.
- chr6:43,770,184–43,786,487, 1 gene, copy number 6: VEGFA.
- chr6:52,497,408–52,577,060, 1 gene, copy number 6 (within-gene range 2–7): TRAM2.
- chr6:68,040,290–68,093,001, 1 gene, copy number 6 (within-gene range 2–6): AL646090.2.
- chr6:71,182,612–71,182,718, 1 gene, copy number 7: RNU6-411P.
- chr6:71,238,743–71,240,947, 1 gene, copy number 5: AL589935.3.
- chr6:99,124,609–99,124,696, 1 gene, copy number 6: MIR548AI.
- chr6:116,877,212–116,932,161, 1 gene, copy number 6 (within-gene range 2–6): RFX6.
- chr6:134,393,142–134,393,900, 1 gene, copy number 7: CHCHD2P4.
- chr6:154,905,076–154,905,206, 1 gene, copy number 7: U8.
- chr6:166,275,462–166,277,077, 1 gene, copy number 6: AL121956.5.

Autosomal genes at a single copy (total copy number 1): 1,411. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
